Somatic mutation profile of tumor specimen TCGA-TM-A84L-01A (aliquot TCGA-TM-A84L-01A-11D-A36O-08) from TCGA case TCGA-TM-A84L, project TCGA-LGG (Brain Lower Grade Glioma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Mixed glioma; Tissue or organ of origin: Cerebrum; Tumor grade: G2; Age at diagnosis: 31.5 years (11,498 days).
Specimen TCGA-TM-A84L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4e04b69c-d7a2-4ed9-a18a-fa27a3a73233.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-TM-A84L-10A (Blood Derived Normal), aliquot TCGA-TM-A84L-10A-01D-A367-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4bf1af00-661d-460a-8c3f-8e618d19af95

The open-access MAF lists 22 somatic variants for this specimen: 16 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 12, Silent 5, 3'Flank 1, Splice Site 1, Frame Shift Ins 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 25/90 reads (28%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.641A>G p.H214R | Missense Mutation (SNP) | VAF 11/32 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as rs1057519992, CM103210, COSV52670202, COSV52732998, COSV52834506, COSV52887765; ClinVar: likely pathogenic; called by muse, varscan2
- TP53 | c.599del p.N200Ifs*47 | Frame Shift Del (DEL) | VAF 10/42 reads (24%) | catalogued as rs1131691011, COSV52677283, COSV52840642, COSV53742336; ClinVar: pathogenic; called by pindel, varscan2
- ATRX | c.2422C>T p.R808* | Nonsense Mutation (SNP) | VAF 89/133 reads (67%) | catalogued as COSV64874953; called by muse, mutect2, varscan2
- CXCR6 | c.983T>C p.F328S | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.49); PolyPhen benign (0); catalogued as rs528341308, COSV99945050; called by muse, mutect2, varscan2
- DSG2 | c.130T>G p.L44V | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.156); catalogued as COSV99852624; called by muse, mutect2, varscan2
- INTU | c.2329G>A p.D777N | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as rs1404066228, COSV58873737; called by muse, mutect2, varscan2
- MYLK4 | c.799C>G p.P267A | Missense Mutation (SNP) | VAF 18/242 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV99193688; called by muse, mutect2
- OR1L4 | c.365A>G p.D122G | Missense Mutation (SNP) | VAF 62/174 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs776896250, COSV99413759; called by muse, varscan2
- PTPN12 | c.1462G>A p.G488S | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as rs1191757654, COSV99949991; called by muse, mutect2, varscan2
- SP2 | c.629T>C p.V210A | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs1479028694, COSV100947089; called by muse, mutect2, varscan2
- TASOR | c.2467A>G p.K823E (on ENST00000355628 / NM_001365636.2; = p.K427E on NM_015224.3) | Missense Mutation (SNP) | VAF 44/122 reads (36%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV100843241; called by muse, mutect2, varscan2
- TMEM171 | c.233G>A p.R78H | Missense Mutation (SNP) | VAF 18/46 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs151305324; called by muse, mutect2, varscan2
- TRERF1 | c.2859+1G>A p.X953_splice | Splice Site (SNP) | VAF 26/90 reads (29%) | catalogued as COSV100549735; called by muse, mutect2, varscan2
- USH2A | c.12694C>A p.P4232T | Missense Mutation (SNP) | VAF 17/125 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs746124303, COSV100227812; called by muse, mutect2
- SLCO1B1 | c.2039dup p.S682Ffs*6 | Frame Shift Ins (INS) | VAF 25/98 reads (26%) | called by mutect2, pindel, varscan2
- APOBEC3F | c.873G>A p.L291= | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as COSV100415081; called by muse, mutect2, varscan2
- INTS1 | c.5052C>T p.S1684= | Silent (SNP) | VAF 3/20 reads (15%) | called by muse, mutect2
- PDE6G | c.33G>C p.R11= | Silent (SNP) | VAF 32/98 reads (33%) | catalogued as COSV100148419; called by muse, mutect2, varscan2
- RAD51AP2 | c.2127G>A p.Q709= | Silent (SNP) | VAF 4/96 reads (4%) | catalogued as COSV101208265, COSV67587204; called by muse, mutect2
- UBXN11 | c.54G>A p.S18= | Silent (SNP) | VAF 20/42 reads (48%) | catalogued as rs753300494, COSV59025414; called by muse, mutect2, varscan2
- RUFY3 | chr4:70793808 G>A | 3'Flank (SNP) | VAF 26/47 reads (55%) | catalogued as rs376846064; called by muse, mutect2, varscan2
